Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A4OT, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A4OT-01A (Primary Tumor).

[page 1 of 2]
PAGE #: 1
SEX: M

PROCEDURE: SPHS

year-old male with history of obesity, gastric stapling, and gastroesophageal reflux. Tumor at GE junction is poorly differentiated infiltrating adenocarcinoma. Clinical Diagnosis: Esophageal carcinoma. Operative Procedure/Tissue Submitted:

ICD-0-3

adenocarcinoma, NOS 8140/3

QCF: Site: esophagus, distal third c15-5
path: GE junction c16.0

PROCEDURE: SPGD

1. "High lesser curvature perigastric soft tissue". Received in a small container is a 1.6 cm soft tissue bit.
Frozen section control.
2. "Thoracic esophagus, stitch marks origin of left gastric artery and celiac node". Received in formalin in a large container is a segment of esophagus (4 cm long x 5.5 cm circumference) with attached proximal stomach (16 cm long x average 6 cm circumference). 8.5 x 5 cm full circumferential ulcer/erosion involving the entire gastroesophageal junction and upper half of proximal stomach. 8.5 cm long x 0.5 cm in diameter fistula tract on the deep periesophageal fibroadipose tissue on the left lateral side, extends from the distal resection margin to a little past the mid point of the stomach. Esophageal mucosal ulceration/erosion is 3 cm from the nearest proximal esophageal margin and 7 cm from the nearest distal stomach margin. Stitch in the deep periesophageal fibroadipose tissue, area inked green. Remaining deep fibroadipose tissue underneath ulcer/erosion inked blue. Tumor invades to a maximal depth of 2 cm, invading through the muscularis and into the adventitia; possibly to the deep resection margin at multiple areas. There are multiple staple lines running along the left lateral side of the distal stomach. Portion of artificial mesh at the distal margin.
- 2A-2C. Full thickness sections of tumor underlying ulcer/erosion with maximal invasion. (Each
- 2D. Area under ulcer/erosion extending to stitch.
- 2E. Tumor involving gastroesophageal junction and extending towards proximal resection margin.
- 2F-2G. Full thickness section from tumor extending to distal resection margin, bisected.
- 2H. Lymph node under tumor, section trisected.
- 2I. One possible lymph node bisected.
- ~~2J. One possible lymph node serially sectioned.~~
- 2K. Three possible lymph nodes.
- 2L. One possible lymph node bisected.
- 2M. Ulcer/erosion with adjacent fistula tract on the left lateral side of the stomach.
3. "Cervical esophageal margin". Received in formalin in a small container is a 1.8 cm long x 1.5 cm in diameter segment of esophagus with staple line at one end. Proximal margin submitted in one cassette.

fw
10/9/12

FROZEN SECTION REPORT

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 2
SEX: M

1. Adenocarcinoma

have reviewed and interpreted the frozen section material at the time it was requested.

have reviewed and interpreted the frozen section material at the time it was requested.

Permanent sections confirm frozen section report.

PROCEDURE: SPMI

ESOPHAGEAL, CARDIAC AND GASTROESOPHAGEAL JUNCTION CARCINOMA:

Type of carcinoma: Adenocarcinoma at the GE junction, not otherwise specified.

Depth of invasion: Adventitia.

Number of positive lymph nodes: 6/11

Extranodal metastasis: Unknown.

Pattern of invasion: Infiltrative.

Esophageal and gastric resection margins involved: No.

Deep resection margin involved: Yes.

TNM classification: T3.N1.Mx

PROCEDURE: SPDX

1-3. Esophagus, transhiatal esophagectomy: Adenocarcinoma arising at the gastroesophageal junction, not otherwise specified. The neoplasm invades through the entire esophageal wall and into the adjacent adventitia. Multiple peripheral soft tissue margins are positive. The neoplasm partially undermines the adjacent squamous mucosa. The esophageal and gastric margins are negative for malignancy. Metastatic adenocarcinoma involving six of the 11 lymph nodes. See template.

Source: NCI Genomic Data Commons file f3680da3-67e7-4cd7-9ef4-4a077a227eed (TCGA-L5-A4OT.2CFE3D9B-50AB-437D-B343-4E30C9A6F956.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).